Somatic mutation profile of tumor specimen TARGET-10-PARNLW-09A (aliquot TARGET-10-PARNLW-09A-01D) from TARGET case TARGET-10-PARNLW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.0 years (5,493 days).
Specimen TARGET-10-PARNLW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae1c312e-d02a-4fcc-83d9-56cb46616be9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARNLW-10A (Blood Derived Normal), aliquot TARGET-10-PARNLW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54285ba5-4015-4ee5-9bda-750ce2634d1c

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL11A2 | c.1457G>T p.R486L (on ENST00000341947 / NM_080680.3; = p.R379L on NM_080679.2) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99051579; called by muse, mutect2
- OR2M4 | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs1415855299; called by muse, mutect2
- MTMR12 | c.2055G>T p.Q685H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.333); called by muse, mutect2
- TAS2R14 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.173); called by muse, mutect2
- AHNAK | c.16533G>T p.V5511= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- SHISA6 | c.327G>A p.E109= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs778109302; called by muse, mutect2
- KALRN | c.4929+8479A>G | Intron (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
